Surgical pathology report (de-identified scan), TCGA case TCGA-MP-A4SY, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Mayo Clinic, specimen TCGA-MP-A4SY-01A (Primary Tumor).

Surgical Pathology
REVISED REPORT (addendum included)

Requested By:

TISSUE DESCRIPTION:

Tissue from right lower lobe lung (204 grams, 15 x 8 x 3 cm), right upper lobe (3.5 x 3.0 x 2.2 cm), inferior mediastinal (subcarinal, inferior pulmonary ligament), superior mediastinal (right and left lower paratracheal), N1 (interlobar), right upper lobe bronchus, right middle lobe bronchus, bronchus intermedius, lymph nodes A1, A2, A3, A4, A5, A6, A7, A8, A9, A10, A11, A12, A13, A14, A15, B1, B2, B3, B4, B5, B6, B7, B8

DIAGNOSIS:

Lung, right lower lobe, lobectomy: Invasive grade 3 (of 4) adenocarcinoma forms a 5 x 4 x 3 cm centrally located mass. The bronchial margin is negative for tumor. One (of 6) intrapulmonary peribronchial lymph nodes is positive for metastatic adenocarcinoma.

Lung, right upper lobe, wedge excision: Necrotizing granuloma.

Lymph nodes, inferior and superior mediastinal, excision: Multiple inferior mediastinal (8 subcarinal), superior mediastinal (5 right lower paratracheal) lymph nodes involved by necrotizing granuloma, negative for tumor.

Lymph nodes, inferior mediastinal, superior mediastinal, N1, bronchus intermedius, right upper lobe bronchus, middle lobe bronchus, excision: Multiple inferior mediastinal (3 subcarinal), superior mediastinal (2 right lower paratracheal), N1 (1 interlobar), (4) bronchus intermedius, (2) right upper lobe bronchus, (1) middle lobe bronchus, lymph nodes show necrotizing granulomatous lymphadenitis.)

Lymph nodes, superior mediastinal, excision: Multiple superior mediastinal (2 left lower paratracheal) lymph nodes are negative for tumor.

Lymph node, inferior mediastinal, excision: Multiple inferior mediastinal (2 inferior pulmonary ligament) lymph nodes are negative for tumor.

ADDENDUM:

Special stains for microorganisms (GMS, auramine-rhodamine) were performed on paraffin-embedded tissue from the subcarinal lymph nodes and have been reported to be negative.

1CD-0-3

adenocarcinoma, NOS 8/40/3
Site: lung, @ lower lobe C34.3

fw
10/29/12

Source: NCI Genomic Data Commons file e6e31c8a-8744-4d30-a1a0-e6b66346488f (TCGA-MP-A4SY.C7A34958-C69B-4EDC-A4D6-503F52BA5330.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).